Surgical pathology report (de-identified scan), TCGA case TCGA-B6-A0RL, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Duke, specimen TCGA-B6-A0RL-01A (Primary Tumor).

[page 1 of 2]
Carcinoma, infiltrating ductal, NOS 8500/3

Site Code: breast, NOS C50.9

1/17/11
for

Surgical

Surg Path

CLINICAL HISTORY:

Left breast mass, positive biopsy. Rule out breast CA.

GROSS EXAMINATION:

A. "Left breast biopsy", in formalin. Received is a portion of adipose tissue which measures 4.5 x 4.0 x 1.9 cm in greatest dimensions. A firm nodule is felt within the adipose tissue. Sections through this nodule reveal a white, gritty mass with irregular borders which measures 3.0 x 1.3 x 2 cm in greatest dimensions. The tumor approaches the margin of resection. Frozen section was done on this tumor. Initially, the tissue is submitted for ER/PR receptors. The frozen section remnant is submitted in Block A1. Additional representative sections of tumor are submitted in Blocks A2 and A3.

B. "Left breast with axillary contents". Received is a 620 gram, 20 x 16 x 3.5 cm modified radical mastectomy with attached axillary tail. The attached axillary tail measures 8 cm x 7.5 cm x 1.8 cm. The skin ellipse measures 20 cm in length x 7.5 cm in width with a medially eccentrically placed nipple. Lateral and inferior to the nipple is a 5 cm sutured incision. The deep surface is painted with blue ink. Deep to the incision there is a hemorrhagic biopsy cavity which measures approximately 5 cm x 4.5 cm x 3 cm in greatest dimensions. The biopsy cavity approaches the deep margin of the specimen, but no residual tumor is identified. Along the superficial edge of the biopsy cavity is a residual firm nodule which measures 1.5 x 2.0 x 0.8 cm is felt. Examination of the remainder of the breast reveals only firm, white breast tissue and adipose tissue. The axillary tail is examined for lymph node candidates.

Block Summary:

- B1: Representative sections of nipple.
B2: Representative sections of skin through incision.
B3-B5: Representative sections of biopsy cavity to include deep margins.
B6, B7: Nodule along superior aspect of biopsy cavity.
B8: Representative section of upper inner quadrant.
B9: Representative sections of lower inner quadrant.
B10: Representative section of upper outer quadrant.
B11: Representative section of normal lower outer quadrant.
B12, B13: Lymph node candidates from Level-I.
B14-B16: Lymph node candidates from Level-II (a single large lymph node candidate is bisected and submitted in toto in Block A16).
B17, B18: Lymph node candidates from Level-III.

INTRA OPERATIVE CONSULTATION:

"Left breast biopsy": AF1 - Carcinoma.

DIAGNOSIS:

A. "LEFT BREAST BIOPSY":

INFILTRATING DUCTAL CARCINOMA (3 CM DIAMETER), NSABP NUCLEAR GRADE 3 of 3
HISTOLOGIC GRADE III. A SPINDLE CELL COMPONENT IS PRESENT.
FOCAL INTRADUCTAL CARCINOMA OF COMEDO TYPE.

B. "LEFT BREAST WITH AXILLARY CONTENTS":

INFILTRATING DUCTAL ADENOCARCINOMA, NSABP NUCLEAR GRADE 2 to 3; HISTOLOGIC
GRADE II.

MDA Discrepancy		X

[page 2 of 2]
SURGICAL MARGINS ARE FREE OF MALIGNANCY.
ZERO OF 16 LYMPH NODES ARE POSITIVE FOR METASTATIC DISEASE.

Verified by

Source: NCI Genomic Data Commons file 8824134b-8b4a-407b-adab-297330b4de4e (TCGA-B6-A0RL.6C50D456-A828-4514-92D2-01A5900B74F1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).